CCDI case PBCMKC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/c8bcc340-13de-4448-9bd6-22ffc8ef884a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Spindle cell carcinoma, NOS: ICD-O-3 morphology code: 8032/3; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 15.6 years (5,705 days).

Biospecimens (3 samples)
- Sample 0DWYUL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWYV5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWYWG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
